Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4816, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4816-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, OPEN LEFT RADICAL NEPHRECTOMY –

A. CONVENTIONAL CLEAR CELL RENAL CELL CARCINOMA (10.

B. FUHRMAN NUCLEAR GRADE 2-3/4.

C. THE RENAL CELL CARCINOMA IS CONFINED WITHIN THE CAPSULE OF THE KIDNEY.

D. THE URETERAL, VASCULAR AND SOFT TISSUE INKED MARGINS OF RESECTION ARE FREE OF TUMOR.

E. UNREMARKABLE ADJACENT RENAL PARENCHYMA.

F. TNM STAGE: T2, NX, MX.

Final Diagnosis

LEVEL 4R MEDIASTINAL LYMPH NODE, BIOPSY

MULTIPLE FRAGMENTS OF CLEAR-CELL CARCINOMA, CONSISTENT WITH METASTATIC RENAL CELL CARCINOMA, FUHRMAN NUCLEAR GRADE 2/4 (see comment).

Comment:

The carcinoma present within the mediastinal tissue biopsy is morphologically similar to the conventional renal cell carcinoma previously resected

A panel of immunoperoxidase stains was performed with the following results referable to the carcinoma cells:

STAIN	USUAL REACTIVITY	RESULT
Cytokeratin CAM 5.2	Some epithelial cells, including renal cell carcinoma	Positive
Epithelial membrane antigen	Epithelial cells subset (including renal cell carcinoma)	Positive
Vimentin	Mesenchymal cells, epithelial subset (including renal cell carcinoma)	Positive
Renal cell carcinoma antigen	Renal epithelial cell neoplasm of proximal tubular differentiation, other	Positive
Thyroid transcription factor	Thyroid and pulmonary epithelial cells	Negative

The clinicopathologic findings are diagnostic of metastatic renal cell carcinoma, conventional (clear cell) type.

Source: NCI Genomic Data Commons file d27518f6-fd71-4ad8-9808-5a50b5216a35 (TCGA-B0-4816.6E66993E-7C75-48AC-97B2-63515A067CCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).